Somatic mutation profile of tumor specimen C3L-02164-03 (aliquot CPT0175260006) from CPTAC case C3L-02164, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 58.2 years (21,252 days).
Specimen C3L-02164-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b22efa8d-964c-4730-bd24-2d044e483cd0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02164-31 (Blood Derived Normal), aliquot CPT0175340002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/16d46d70-aa4f-4c51-9089-e2c9539b8293

The open-access MAF lists 5 somatic variants for this specimen: 5 protein-altering or splice-affecting.
By variant classification: Missense Mutation 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DACH2 | c.1534A>G p.R512G | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); called by muse, mutect2
- FGF10 | c.463A>G p.R155G | Missense Mutation (SNP) | VAF 14/402 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- GHSR | c.650C>A p.S217Y | Missense Mutation (SNP) | VAF 26/574 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2
- MYO10 | c.2387A>T p.Q796L | Missense Mutation (SNP) | VAF 15/476 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NIPBL | c.1970G>A p.R657K | Missense Mutation (SNP) | VAF 12/295 reads (4%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0); called by muse, mutect2
